Gene-level copy-number profile of tumor specimen TCGA-R6-A6L4-01A from TCGA case TCGA-R6-A6L4, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 28.0 years (10,222 days).
Specimen TCGA-R6-A6L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d2b593cf-814f-45c2-82c8-5671d1fe24df.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6L4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba27590a-feb1-407e-ab78-14d56dfeaf7f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 2: 39,486; copy number 3: 2,667; copy number 4: 16,153; copy number 5: 283; copy number 6: 796; copy number 7: 299; copy number 8: 85; copy number 12: 11; copy number 13: 14; copy number 21: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6L4-01A-11D-A31T-01): tumor purity 0.61, ploidy 1.4, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,749,342–246,507,312, 1 gene (within-gene range 0–4): SMYD3.
- chr1:246,108,626–246,426,119, 5 genes: SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1, Y_RNA.
- chr3:114,445,521–114,529,452, 1 gene: ZBTB20-AS5.
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.
- chr16:78,495,926–78,553,296, 4 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,494 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:25,349,841–45,895,970, 302 genes, copy number 5–7 (broad region; genes not listed).
- chr7:70,972–3,302,452, 84 genes, copy number 8 (broad region; genes not listed).
- chr7:3,337,889–3,338,601, 1 gene, copy number 8: AC092427.1.
- chr7:4,511,959–48,927,454, 780 genes, copy number 6 (broad region; genes not listed).
- chr8:35,080,592–36,936,125, 20 genes, copy number 13–21: AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8.
- chr8:70,357,347–81,112,068, 164 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:123,002,560–129,844,504, 124 genes, copy number 7–12 (broad region; genes not listed).
- chr8:129,864,478–129,901,758, 3 genes, copy number 7: AC022973.2, AC022973.1, AC022973.4.
- chr20:5,750,393–6,123,030, 16 genes, copy number 6 (within-gene range 4–6): SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
